Somatic mutation profile of tumor specimen CDDP-A8B7-TTP2-C (aliquot CDDP-A8B7-TTP2-C-1-0-D-A500-36) from CDDP_EAGLE case CDDP-A8B7, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71 years.
Specimen CDDP-A8B7-TTP2-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1e297b8-38d7-4e76-b3b4-94a0de657212.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-A8B7-NB1-A (Blood Derived Normal), aliquot CDDP-A8B7-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/922b9d0c-7745-417a-8374-3b97ddb39840

The open-access MAF lists 186 somatic variants for this specimen: 120 protein-altering or splice-affecting, 44 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 44, Intron 12, Nonsense Mutation 5, Splice Site 4, 3'UTR 4, 5'Flank 3, 5'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD3B2 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs80358221, CM950656, CM993171; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/270 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs1233948189; called by muse, mutect2
- APCS | c.208T>C p.S70P | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54819150; called by muse, mutect2, varscan2
- ARHGAP15 | c.231A>T p.Q77H | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54519280; called by muse, mutect2, varscan2
- ARHGAP6 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57302765; called by muse, mutect2, varscan2
- ARMC4 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 57/369 reads (15%) | catalogued as COSV59472935; called by muse, mutect2, varscan2
- ASPH | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 25/278 reads (9%) | catalogued as COSV62861258; called by muse, mutect2
- ATF7IP2 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.148); catalogued as rs1480088785, COSV61095281; called by muse, mutect2
- ATM | c.6812C>A p.P2271H | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as CD961808, COSV53771881, COSV99592534; called by muse, mutect2, varscan2
- BAZ1B | c.4418T>C p.V1473A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1554565189; called by muse, mutect2, varscan2
- BCKDHB | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 56/373 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.228); catalogued as COSV100244293, COSV57518349; called by muse, varscan2
- BUD23 | c.722G>T p.R241M | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV56096180; called by muse, mutect2, varscan2
- CCT6A | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51907540; called by muse, mutect2
- CENPE | c.3706G>A p.E1236K | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV54389220; called by muse, mutect2
- CLCNKA | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58893748; called by muse, mutect2, varscan2
- CLEC3A | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.578); catalogued as rs773789936; called by muse, mutect2, varscan2
- CLTCL1 | c.1429A>T p.S477C | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54238458; called by muse, mutect2, varscan2
- CNTLN | c.1759A>G p.S587G | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.269); catalogued as COSV52095866; called by muse, mutect2
- CORO7 | c.2698A>G p.M900V | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as rs1253888268, COSV52033747; called by muse, mutect2, varscan2
- COX20 | c.131C>G p.A44G | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV63674041; called by muse, mutect2, varscan2
- CYP7A1 | c.1278T>A p.N426K | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV56965607; called by muse, mutect2, varscan2
- CYYR1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as rs952763494, COSV54837482; called by muse, mutect2, varscan2
- DNM2 | c.237A>G p.E79= | Splice Region (SNP) | VAF 31/320 reads (10%) | catalogued as COSV58971314; called by muse, mutect2
- ECE1 | c.815C>G p.T272S | Missense Mutation (SNP) | VAF 51/338 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV51670097; called by muse, mutect2, varscan2
- ERICH6 | c.1936G>T p.G646C | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55803061; called by muse, mutect2
- FAM193A | c.3649G>A p.D1217N (on ENST00000324666 / NM_001256666.1; = p.D1176N on NM_003704.3) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100219748; called by muse, mutect2
- FAM47B | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772125971, COSV61453189; called by muse, mutect2, varscan2
- FAM71B | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs543304286, COSV57229990; called by muse, mutect2
- FREM1 | c.4954A>T p.T1652S | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.412); catalogued as COSV66529655; called by muse, mutect2
- FRS3 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV52486733; called by muse, mutect2
- GJA10 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781637673, COSV65355601, COSV65355609; called by muse, mutect2, varscan2
- HDAC11 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs753220024, COSV99849882; called by muse, mutect2
- HMCN1 | c.14923G>T p.A4975S | Missense Mutation (SNP) | VAF 66/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54937962; called by muse, mutect2, varscan2
- IGDCC3 | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60080064; called by muse, mutect2, varscan2
- JAK3 | c.331G>T p.G111W | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71687535; called by muse, mutect2
- KCNC4 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as rs999658273, COSV63926602; called by muse, mutect2
- KCND2 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58601709; called by muse, mutect2
- KCNK1 | c.836T>A p.M279K | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV64036381; called by muse, mutect2, varscan2
- KDM6A | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1408680060, COSV100938031, COSV65041121; called by muse, mutect2, varscan2
- KIF21B | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59761876, COSV59765501; called by muse, mutect2, varscan2
- KIR2DL3 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1290119985, COSV60900586; called by muse, mutect2, varscan2
- KLF8 | c.561G>C p.M187I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV63848798; called by muse, mutect2, varscan2
- KMT2D | c.4351A>T p.S1451C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56471260; called by muse, mutect2, varscan2
- LAG3 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52569236; called by muse, mutect2, varscan2
- LCK | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV60742504; called by muse, mutect2
- LOXHD1 | c.4331G>T p.G1444V | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56070520; called by muse, mutect2, varscan2
- LRBA | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV63963980; called by muse, mutect2, varscan2
- MACROH2A1 | c.695C>T p.T232M (on ENST00000510038; = p.T231M on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs1198608345; called by muse, mutect2, varscan2
- MANEA | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs769309628, COSV62590482; called by muse, mutect2, varscan2
- MMRN1 | c.1676T>A p.M559K | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV53342060; called by muse, mutect2
- MMRN1 | c.1677G>T p.M559I | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53342071; called by muse, mutect2
- MYCBP2 | c.13687T>C p.Y4563H (on ENST00000357337; = p.Y4601H on NM_015057.5) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62037664; called by muse, mutect2, varscan2
- NR5A1 | c.992T>G p.V331G | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV65295590; called by muse, mutect2
- OR2C1 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV59239872, COSV59241260; called by muse, mutect2, varscan2
- OR6Q1 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV56934516; called by muse, mutect2, varscan2
- OR8H2 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.611); catalogued as COSV100542556; called by muse, mutect2
- PAPPA2 | c.962G>A p.W321* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as rs1431085725, COSV62785924; called by muse, varscan2
- PAWR | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60924889; called by muse, mutect2
- PCCB | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV52446754; called by muse, mutect2
- PCDH17 | c.2859C>A p.C953* | Nonsense Mutation (SNP) | VAF 34/160 reads (21%) | catalogued as COSV64971588, COSV64978715; called by muse, mutect2, varscan2
- PCDHB15 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV51379692; called by muse, mutect2, varscan2
- PCDHGB7 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV54023266; called by muse, mutect2, varscan2
- PLCE1 | c.2255G>T p.R752L | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53349308; called by muse, mutect2
- PLPPR3 | c.1094T>C p.M365T (on ENST00000520876 / NM_001270366.2; = p.M393T on NM_024888.2) | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV62461660; called by muse, mutect2
- PP2D1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV60749583; called by muse, mutect2
- PRORP | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51622854; called by muse, mutect2
- PRR12 | c.2543G>A p.R848Q (on ENST00000615927; = p.R1669Q on NM_020719.3) | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1446465070; called by muse, mutect2
- PRRT4 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV71055032; called by muse, mutect2, varscan2
- RANBP17 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV66656509; called by muse, mutect2, varscan2
- RASGRP3 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67824915; called by muse, mutect2
- RMND1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1277923243; called by muse, mutect2, varscan2
- RPF2 | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV64370647; called by mutect2, varscan2
- SLC35C2 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs769892083, COSV54758416; called by muse, mutect2
- SLC6A15 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as COSV57029168; called by muse, mutect2, varscan2
- SLC7A9 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 65/407 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV50093224; called by muse, mutect2, varscan2
- SLCO2A1 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1345912923, COSV60489134; called by muse, mutect2, varscan2
- SPACA1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 27/296 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV52759235; called by muse, mutect2
- STK32B | c.509T>A p.V170E | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.284); catalogued as COSV51511327, COSV99286585; called by muse, mutect2
- SUPT5H | c.1377C>G p.D459E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63241908; called by muse, mutect2
- TAS1R1 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV60230049; called by muse, mutect2
- TENM3 | c.2144G>T p.R715L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.714); catalogued as rs776348291, COSV69318231, COSV99072710; called by muse, mutect2, varscan2
- THADA | c.4924G>T p.A1642S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs745832871, COSV57692519; called by muse, mutect2
- TMPRSS2 | c.1472A>T p.D491V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV59827163; called by muse, mutect2, varscan2
- TP53 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52689817, COSV52759537, COSV52925149; called by muse, mutect2
- TRIM62 | c.296T>G p.V99G | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.438); catalogued as COSV52223458; called by muse, mutect2, varscan2
- TRPM6 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV62515247; called by muse, mutect2
- TTN | c.80343A>T p.R26781S (on ENST00000591111; = p.R19357S on NM_003319.4) | Missense Mutation (SNP) | VAF 20/151 reads (13%) | PolyPhen probably damaging (0.996); catalogued as COSV60317028; called by muse, mutect2, varscan2
- USH2A | c.7503A>T p.Q2501H | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV56429357; called by muse, mutect2, varscan2
- UTP20 | c.7802C>G p.S2601C | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV55384729; called by muse, mutect2
- VWA2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV53906158; called by muse, mutect2, varscan2
- ZDBF2 | c.2230G>T p.D744Y | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV65629690; called by muse, mutect2, varscan2
- ZEB2 | c.2165C>A p.P722H | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV57965517; called by muse, mutect2
- ZNF716 | c.548A>T p.K183I | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV70782975; called by muse, mutect2
- ZNF837 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1181349377, COSV69893339; called by muse, mutect2
- ZNF99 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101233883; called by muse, mutect2
- ATE1 | c.584-2A>C p.X195_splice | Splice Site (SNP) | VAF 14/123 reads (11%) | called by muse, varscan2
- ATP6V0C | c.80-1G>T p.X27_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | called by muse, varscan2
- C9 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.357); called by muse, mutect2
- CHEK2 | c.1397G>T p.G466V (on ENST00000382580 / NM_001005735.2; = p.G423V on NM_007194.4) | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKH | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.101); called by muse, mutect2
- DIS3L | c.171_173del p.Y58del | In Frame Del (DEL) | VAF 13/132 reads (10%) | called by mutect2, pindel, varscan2
- ERN1 | c.2831C>T p.T944I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2
- FAT2 | c.10700G>A p.S3567N | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2
- FBXO38 | c.2468G>T p.G823V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FLT1 | c.388+1del p.X130_splice | Splice Site (DEL) | VAF 38/141 reads (27%) | called by mutect2, pindel, varscan2
- GGH | c.303C>A p.D101E | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- GPHN | c.439A>G p.S147G | Missense Mutation (SNP) | VAF 19/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- MEX3A | c.547_548insT p.R183Lfs*81 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- MYT1L | c.787del p.D263Tfs*6 | Frame Shift Del (DEL) | VAF 45/300 reads (15%) | called by mutect2, pindel, varscan2
- NBAS | c.2962C>A p.Q988K | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2
- OR5M1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PRKDC | c.11200A>T p.R3734W | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RNF6 | c.448A>T p.S150C | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SIRT1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2
- SLIT3 | c.1974-2A>G p.X658_splice | Splice Site (SNP) | VAF 19/97 reads (20%) | called by mutect2, varscan2
- SPRY3 | c.238A>T p.S80C | Missense Mutation (SNP) | VAF 71/432 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SSTR2 | c.438C>A p.H146Q | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TMPO | c.1400A>T p.H467L | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); called by muse, mutect2
- UPF3B | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- AGBL1 | c.1725A>G p.K575= | Silent (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- AKIRIN2 | c.171G>T p.S57= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57637587; called by muse, varscan2
- ANO3 | c.1512C>T p.I504= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1220422100, COSV56782510; called by muse, mutect2, varscan2
- CILP | c.2355C>A p.G785= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV56027612; called by muse, mutect2, varscan2
- DARS1 | c.510A>T p.G170= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV51541794; called by muse, mutect2
- DAW1 | c.144C>A p.I48= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV59367524, COSV59368794; called by muse, mutect2, varscan2
- DICER1 | c.1698A>T p.T566= | Silent (SNP) | VAF 17/292 reads (6%) | called by muse, mutect2
- DLG5 | c.5196G>A p.Q1732= | Silent (SNP) | VAF 41/219 reads (19%) | catalogued as rs1029976397, COSV64949789; called by muse, mutect2, varscan2
- DSG4 | c.783C>T p.D261= | Silent (SNP) | VAF 41/440 reads (9%) | catalogued as rs771033904; called by muse, mutect2
- GLI3 | c.1317C>G p.P439= | Silent (SNP) | VAF 32/334 reads (10%) | called by muse, mutect2, varscan2
- GPHN | c.438T>A p.G146= | Silent (SNP) | VAF 20/346 reads (6%) | called by muse, mutect2
- H4C12 | c.303C>T p.F101= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV62744021; called by muse, mutect2, varscan2
- IL1A | c.436C>A p.R146= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV54519167, COSV54520321; called by muse, mutect2, varscan2
- LHFPL4 | c.198G>T p.V66= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV55004694; called by muse, mutect2
- MAN1A1 | c.429C>T p.P143= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as rs775843176, COSV63784671; called by muse, mutect2, varscan2
- MAP3K19 | c.813G>A p.S271= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs772166646, COSV59638066; called by muse, mutect2, varscan2
- NEK5 | c.1899T>C p.F633= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV62881811; called by muse, mutect2, varscan2
- NHLH2 | c.96C>T p.L32= | Silent (SNP) | VAF 20/356 reads (6%) | called by muse, mutect2
- NOXO1 | c.849G>T p.A283= (on ENST00000397280 / NM_172168.3; = p.A277= on NM_144603.4) | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as COSV50191869; called by muse, mutect2
- NTRK3 | c.1644C>A p.A548= | Silent (SNP) | VAF 67/356 reads (19%) | catalogued as COSV62314481; called by muse, mutect2, varscan2
- PCDHA1 | c.2160G>T p.A720= | Silent (SNP) | VAF 30/340 reads (9%) | catalogued as rs1554118257, COSV65372448, COSV65372794, COSV65375315; called by muse, mutect2
- PCDHB9 | c.2217G>T p.V739= | Silent (SNP) | VAF 22/380 reads (6%) | called by muse, mutect2
- PIK3C2B | c.3828C>T p.L1276= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs773864326, COSV65814066; called by muse, mutect2, varscan2
- PLCH1 | c.4050C>G p.L1350= (on ENST00000340059 / NM_001130960.2; = p.L1342= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as COSV58209258; called by muse, mutect2
- PODNL1 | c.1221C>T p.D407= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- RPS6KA3 | c.513A>G p.K171= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV65389315; called by muse, mutect2, varscan2
- RTN1 | c.1224G>T p.S408= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs757743369, COSV50745812; called by muse, mutect2, varscan2
- SIGLECL1 | c.189C>A p.G63= | Silent (SNP) | VAF 42/268 reads (16%) | catalogued as COSV57064563; called by muse, mutect2, varscan2
- SIGMAR1 | c.198G>A p.R66= | Silent (SNP) | VAF 16/256 reads (6%) | catalogued as rs756841280, COSV52844995; called by muse, mutect2
- SLC8A3 | c.2121C>A p.T707= (on ENST00000381269 / NM_183002.3; = p.T705= on NM_033262.4) | Silent (SNP) | VAF 23/169 reads (14%) | catalogued as rs771418729, COSV53692399, COSV53692461; called by muse, mutect2, varscan2
- SMG9 | c.1020G>C p.V340= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV54216221; called by muse, mutect2, varscan2
- SPATA31E1 | c.3039T>C p.S1013= | Silent (SNP) | VAF 30/316 reads (9%) | catalogued as rs375176795; called by muse, mutect2
- TBX4 | c.1497A>G p.Q499= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs1054136449; called by muse, mutect2, varscan2
- TMEM192 | c.744C>T p.H248= | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as COSV60586148; called by muse, mutect2
- TMLHE | c.510C>T p.F170= | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as rs1557334327, COSV57686890; called by muse, mutect2, varscan2
- TTC5 | c.636A>G p.Q212= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV51872169; called by muse, mutect2, varscan2
- TTN | c.58137G>A p.E19379= (on ENST00000591111; = p.E11955= on NM_003319.4) | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as rs1391810054; ClinVar: likely benign; called by muse, mutect2
- TUSC1 | c.330C>G p.L110= | Silent (SNP) | VAF 18/275 reads (7%) | catalogued as COSV63662139; called by muse, mutect2
- VCAN | c.888C>T p.Y296= | Silent (SNP) | VAF 19/237 reads (8%) | catalogued as rs1240096785, COSV54105886; called by muse, mutect2
- WNK4 | c.3528G>A p.V1176= | Silent (SNP) | VAF 15/220 reads (7%) | called by muse, mutect2
- ZNF160 | c.2346C>T p.I782= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ZNF169 | c.534G>A p.G178= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as rs758620333, COSV61766444; called by muse, mutect2, varscan2
- ZNF704 | c.744C>T p.D248= | Silent (SNP) | VAF 35/430 reads (8%) | catalogued as rs368468965; called by muse, mutect2
- ZNF90 | c.1356C>T p.P452= | Silent (SNP) | VAF 24/278 reads (9%) | catalogued as rs782161502; called by muse, mutect2
- AFF1 | c.1038+2080C>T | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as rs377248984, COSV100320451; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499479 G>T | 5'Flank (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- ARNTL | c.1326-64G>A | Intron (SNP) | VAF 16/94 reads (17%) | called by mutect2, varscan2
- BIRC6 | c.12291+686A>T | Intron (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- CASR | c.1378-6128G>T | Intron (SNP) | VAF 36/337 reads (11%) | catalogued as rs778647030, COSV56141131; called by muse, mutect2, varscan2
- DVL1 | c.-28_-17del | 5'UTR (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel*, varscan2*
- FCN1 | c.*118C>A | 3'UTR (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- GCNT2 | c.926-34957G>A | Intron (SNP) | VAF 40/158 reads (25%) | catalogued as rs1192323024, COSV53944255; called by muse, mutect2, varscan2
- IWS1 | c.-220C>T | 5'UTR (SNP) | VAF 16/160 reads (10%) | catalogued as rs565971619; called by muse, mutect2, varscan2
- KLF6 | c.*1233G>C | 3'UTR (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- LINC02693 | n.769dup | RNA (INS) | VAF 11/70 reads (16%) | catalogued as rs1318472651; called by mutect2, pindel, varscan2
- LRRC74A | c.217+81C>A | Intron (SNP) | VAF 30/445 reads (7%) | called by muse, mutect2
- Metazoa_SRP | chr17:20339970 G>T | 5'Flank (SNP) | VAF 30/360 reads (8%) | catalogued as rs1196760796; called by muse, mutect2
- PLCH2 | c.2959+581G>A | Intron (SNP) | VAF 26/187 reads (14%) | catalogued as rs1448405816, COSV53938765; called by muse, mutect2, varscan2
- RNF41 | c.90+919G>T | Intron (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- SLC16A5 | c.-48-155G>A | Intron (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- SORBS1 | c.442-1030T>G | Intron (SNP) | VAF 26/373 reads (7%) | called by muse, mutect2
- TENT4A | c.1246-10_1246-9dup | Intron (INS) | VAF 16/114 reads (14%) | called by mutect2, pindel*, varscan2*
- TRIM74 | chr7:72969944 C>G | 5'Flank (SNP) | VAF 18/521 reads (3%) | called by muse, mutect2
- ULK1 | c.*746C>A | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- USH2A | c.4627+37G>A | Intron (SNP) | VAF 20/242 reads (8%) | catalogued as rs749410282, COSV100238797, COSV100243210; called by muse, mutect2
- XPO5 | c.*12G>A | 3'UTR (SNP) | VAF 56/300 reads (19%) | called by muse, mutect2, varscan2
